Gene-level copy-number profile of tumor specimen ALCH-B464-TTP1-A from ALCHEMIST case ALCH-B464, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.7 years (22,538 days).
Specimen ALCH-B464-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 01f2a367-4081-40b5-a980-ad80fdd55de3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B464-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/d982f5aa-3d01-43b9-9101-d56081017a13

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 2,929; copy number 2: 55,683; copy number 3: 210; copy number 4: 9; copy number 5: 59; copy number 6: 1; copy number 11: 1; copy number 18: 2.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,693,124–7,698,872, 2 genes (within-gene range 0–2): AL359881.3, AL359881.2.
- chr2:232,385,750–232,421,461, 4 genes: ECEL1P2, ALPG, ECEL1P1, AC068134.2.
- chr2:232,456,125–232,487,834, 2 genes: ALPI, ECEL1.
- chr22:18,906,028–18,947,732, 3 genes (within-gene range 0–6): DGCR6, AC007326.4, PRODH.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 63 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:64,637,845–64,709,311, 2 genes, copy number 18: AL445665.1, BMS1P11.
- chr14:22,040,594–22,494,883, 58 genes, copy number 5: TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44.
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.
- chr22:18,936,411–18,947,741, 1 gene, copy number 6 (within-gene range 0–6): AC007326.5.
- chr22:21,141,624–21,142,371, 1 gene, copy number 11: E2F6P2.

Autosomal genes at a single copy (total copy number 1): 73. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
